Somatic mutation profile of tumor specimen TCGA-BA-5555-01A (aliquot TCGA-BA-5555-01A-01D-1512-08) from TCGA case TCGA-BA-5555, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.6 years (19,956 days).
Specimen TCGA-BA-5555-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee0887be-875e-40c2-914b-1aa644c8477a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-5555-10A (Blood Derived Normal), aliquot TCGA-BA-5555-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c653c97-4e0e-474e-b416-5ae35b79bfe4

The open-access MAF lists 146 somatic variants for this specimen: 118 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 100, Silent 27, Nonsense Mutation 11, Frame Shift Ins 3, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.2362C>T p.R788* | Nonsense Mutation (SNP) | VAF 39/86 reads (45%) | catalogued as rs1057520339, CM052298, COSV61779938, COSV61779986; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 50/87 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2504A>T p.Q835L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV100217331, COSV56854462; called by muse, mutect2, varscan2
- ACTC1 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99291720, COSV99291888; called by muse, mutect2, varscan2
- ADGRF2 | c.912A>C p.K304N (on ENST00000296862 / NM_001368115.2; = p.K236N on NM_153839.7) | Missense Mutation (SNP) | VAF 93/392 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as COSV99731308; called by muse, mutect2, varscan2
- AKAP13 | c.5791G>A p.D1931N (on ENST00000394518 / NM_007200.5; = p.D1935N on NM_006738.6) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773903; called by muse, mutect2, varscan2
- AKAP9 | c.10963G>C p.D3655H (on ENST00000359028; = p.D3631H on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100662225, COSV100662480; called by muse, mutect2, varscan2
- AKR1B10 | c.127A>C p.I43L | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV100610202; called by muse, mutect2, varscan2
- AMIGO2 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV56973509, COSV99873618; called by muse, mutect2, varscan2
- AMY2A | c.383G>T p.S128I | Missense Mutation (SNP) | VAF 74/750 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV101340643; called by muse, mutect2, varscan2
- ANAPC1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as rs752960301, COSV100594792; called by muse, mutect2, varscan2
- ARHGAP6 | c.1165G>T p.A389S | Missense Mutation (SNP) | VAF 178/284 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as COSV100272960; called by muse, mutect2, varscan2
- ARL6IP6 | c.505A>T p.S169C | Missense Mutation (SNP) | VAF 118/359 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV100424023; called by muse, mutect2, varscan2
- ASAP1 | c.221T>A p.V74E | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100727336; called by muse, mutect2, varscan2
- BRINP2 | c.1474C>G p.R492G | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV100838119; called by muse, mutect2, varscan2
- C2CD5 | c.1367A>T p.E456V | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100448799; called by muse, mutect2, varscan2
- C7 | c.2465C>T p.A822V | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV100495896; called by muse, mutect2, varscan2
- CASQ2 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 111/340 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as COSV54772010, COSV99797783; called by muse, mutect2, varscan2
- CASQ2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs750680032, COSV99797786; called by muse, mutect2, varscan2
- CBLIF | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 116/431 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV99950970; called by muse, mutect2, varscan2
- CDC14A | c.1586C>T p.P529L | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.261); catalogued as COSV100324661, COSV100325233; called by muse, mutect2, varscan2
- CDH5 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.243); catalogued as COSV100439268; called by muse, mutect2, varscan2
- CDH7 | c.1026A>T p.E342D | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs778103076, COSV100542499, COSV59893566; called by muse, mutect2, varscan2
- CDH7 | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100541191, COSV59883801; called by muse, mutect2, varscan2
- CEP192 | c.5107A>T p.K1703* | Nonsense Mutation (SNP) | VAF 59/225 reads (26%) | catalogued as COSV100381371; called by muse, mutect2, varscan2
- CEP41 | c.1012A>T p.K338* | Nonsense Mutation (SNP) | VAF 113/306 reads (37%) | catalogued as COSV99782736; called by muse, mutect2, varscan2
- CLCN2 | c.2414A>C p.K805T | Missense Mutation (SNP) | VAF 564/737 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99658635; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1407A>T p.Q469H | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99600038; called by muse, mutect2, varscan2
- DMRTB1 | c.155C>A p.A52E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101008333, COSV65113847; called by muse, mutect2
- DNAH8 | c.1793T>C p.L598P | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as COSV100545679; called by muse, mutect2, varscan2
- ENPEP | c.2579A>G p.N860S | Missense Mutation (SNP) | VAF 128/264 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV99487652; called by muse, mutect2, varscan2
- ENTPD1 | c.74C>A p.S25Y | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.231); catalogued as COSV100967573; called by muse, mutect2, varscan2
- EPAS1 | c.1219C>A p.P407T | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV99763275; called by muse, mutect2, varscan2
- EYA1 | c.427T>C p.W143R | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs773097343, COSV100379217; called by muse, mutect2, varscan2
- FAM13B | c.641A>T p.N214I | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV99221456; called by muse, mutect2, varscan2
- FBN2 | c.5071G>C p.E1691Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV99327971; called by muse, mutect2, varscan2
- FCRLA | c.410G>A p.R137Q (on ENST00000367959; = p.R114Q on NM_032738.4) | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as rs145034072, COSV52684449; called by muse, mutect2, varscan2
- FER1L6 | c.3440C>T p.P1147L | Missense Mutation (SNP) | VAF 83/210 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs866324197, COSV101205915, COSV67553064; called by muse, varscan2
- FNIP2 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 126/252 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100032746; called by muse, mutect2, varscan2
- FOXP1 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.189); catalogued as COSV100561807; called by muse, mutect2, varscan2
- GIMAP4 | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV55431601, COSV99750709; called by muse, mutect2, varscan2
- GLB1L3 | c.531G>C p.W177C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101111071, COSV66281969; called by muse, varscan2
- GOLGA5 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs200288795; called by muse, mutect2, varscan2
- GON4L | c.2074C>T p.Q692* | Nonsense Mutation (SNP) | VAF 116/304 reads (38%) | catalogued as COSV99674518; called by muse, mutect2, varscan2
- HCN1 | c.2540C>A p.S847* | Nonsense Mutation (SNP) | VAF 50/250 reads (20%) | catalogued as COSV100300556; called by muse, mutect2, varscan2
- HLA-DQA2 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 108/622 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100890728; called by muse, varscan2
- HSDL2 | c.946A>G p.I316V | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV99356897; called by muse, mutect2, varscan2
- ICAM1 | c.437T>A p.L146H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320860; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100147488; called by muse, mutect2, varscan2
- JMJD4 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.045); catalogued as COSV100248214; called by muse, mutect2, varscan2
- KDM2B | c.3455G>A p.R1152Q | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1050223900, COSV100997432; called by muse, mutect2, varscan2
- KLRG1 | c.489C>A p.C163* | Nonsense Mutation (SNP) | VAF 40/137 reads (29%) | catalogued as rs145154967, COSV99868366; called by muse, mutect2, varscan2
- KRTAP5-11 | c.57_77del p.S21_G27del | In Frame Del (DEL) | VAF 30/79 reads (38%) | catalogued as rs750194493; called by muse*, mutect2
- LDHB | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as COSV63364852; called by muse, varscan2
- LINGO2 | c.66G>C p.M22I | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV100430628; called by muse, mutect2
- LRRC4C | c.705G>T p.R235S | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99538500; called by muse, mutect2, varscan2
- MAP1B | c.5515G>A p.D1839N | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.32); catalogued as rs754067983, COSV57094967; called by muse, mutect2, varscan2
- MAP3K7CL | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 161/279 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV54509619, COSV54510297; called by muse, mutect2, varscan2
- MAP4K4 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100154960; called by muse, mutect2, varscan2
- MICAL3 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV99261741; called by muse, mutect2, varscan2
- MUC16 | c.38321G>A p.R12774H | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs548938808, COSV67485780; called by muse, mutect2, varscan2
- NMS | c.151A>T p.S51C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV100966605; called by muse, mutect2, varscan2
- NOTCH4 | c.4240G>A p.A1414T | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs767518997, COSV100900703; called by muse, mutect2, varscan2
- NUP188 | c.1394A>G p.Y465C | Missense Mutation (SNP) | VAF 120/510 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101001372; called by muse, mutect2, varscan2
- OR10R2 | c.230C>A p.T77K | Missense Mutation (SNP) | VAF 200/569 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100936798, COSV63769211; called by muse, mutect2, varscan2
- OR10Z1 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 132/466 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100779030, COSV63523732; called by muse, mutect2, varscan2
- OR2T1 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100822320; called by muse, mutect2, varscan2
- OR4M1 | c.336G>C p.M112I | Missense Mutation (SNP) | VAF 160/796 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.081); catalogued as COSV100271103, COSV100271241; called by muse, mutect2, varscan2
- OR56A1 | c.739C>A p.H247N | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100360423, COSV100360484; called by muse, mutect2, varscan2
- OR5D14 | c.300G>T p.M100I | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100162394, COSV59458739; called by muse, mutect2, varscan2
- PAX5 | c.256T>C p.S86P | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100814308; called by muse, mutect2, varscan2
- PCDH9 | c.2806G>T p.A936S | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100121196; called by muse, mutect2, varscan2
- PCLO | c.9535G>C p.D3179H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100433331; called by muse, mutect2, varscan2
- PDE1C | c.42C>A p.C14* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV101275540, COSV68809302; called by muse, mutect2, varscan2
- PGBD1 | c.2058G>C p.L686F | Missense Mutation (SNP) | VAF 94/427 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.374); catalogued as COSV99460359; called by muse, mutect2, varscan2
- PIGT | c.322T>A p.S108T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV99649003; called by muse, mutect2, varscan2
- PIWIL1 | c.2244T>G p.F748L | Missense Mutation (SNP) | VAF 49/257 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99806474; called by muse, mutect2, varscan2
- PLXNB2 | c.2931C>G p.F977L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100834094; called by muse, mutect2, varscan2
- POTEE | c.1940A>G p.E647G | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as COSV100388076; called by muse, mutect2, varscan2
- PPP1R9A | c.2179G>T p.E727* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV99195815; called by muse, mutect2, varscan2
- PTPN4 | c.2153G>T p.S718I | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV99750369; called by muse, mutect2, varscan2
- RNFT1 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 94/167 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1231140351, COSV99994431; called by muse, mutect2, varscan2
- RTN4 | c.2983A>G p.I995V | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs201229603; called by muse, mutect2, varscan2
- RYR3 | c.3598C>A p.R1200S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV101212898; called by muse, mutect2, varscan2
- SALL3 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.669); catalogued as rs1445504425, COSV101610009; called by muse, mutect2, varscan2
- SDK1 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs148101694; called by muse, mutect2, varscan2
- SERPINB8 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.93); catalogued as rs150328649, COSV54639280; called by muse, mutect2, varscan2
- SH3GLB1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 34/237 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.173); catalogued as rs1352154834, COSV100990784; called by muse, mutect2, varscan2
- SHPK | c.640G>T p.V214L | Missense Mutation (SNP) | VAF 137/214 reads (64%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99843864; called by muse, mutect2, varscan2
- SLC35F5 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV99830076; called by muse, mutect2, varscan2
- SLC4A4 | c.3145A>G p.M1049V (on ENST00000264485 / NM_001098484.3; = p.M1005V on NM_003759.4) | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.54); catalogued as rs150809470; called by muse, mutect2, varscan2
- SLITRK6 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 78/181 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1263919085, COSV101233240; called by muse, mutect2, varscan2
- SMAD4 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV61689229; called by muse, mutect2
- SSX2IP | c.286A>G p.I96V | Missense Mutation (SNP) | VAF 68/179 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100642602; called by muse, mutect2, varscan2
- TEP1 | c.4762+1G>A p.X1588_splice | Splice Site (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99402527; called by muse, mutect2, varscan2
- TFRC | c.1909C>A p.L637M | Missense Mutation (SNP) | VAF 139/247 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100786504; called by muse, mutect2, varscan2
- THSD4 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99965788; called by muse, mutect2, varscan2
- TRIM67 | c.2227G>A p.A743T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100792136; called by muse, mutect2, varscan2
- TRPV6 | c.1765G>T p.V589L | Missense Mutation (SNP) | VAF 84/267 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100844328; called by muse, mutect2, varscan2
- TTC27 | c.811T>A p.L271M | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as COSV100513127; called by muse, mutect2, varscan2
- TTLL12 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV99333519; called by muse, mutect2, varscan2
- UNC80 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.757); catalogued as COSV99779727; called by muse, mutect2, varscan2
- UPF1 | c.425A>G p.K142R | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV99439684; called by muse, mutect2, varscan2
- VEZT | c.560T>A p.L187* | Nonsense Mutation (SNP) | VAF 140/362 reads (39%) | catalogued as COSV99703986; called by muse, mutect2, varscan2
- VWA3A | c.1094C>A p.A365E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100240952; called by muse, mutect2
- ZNF106 | c.76G>T p.G26W | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55513481, COSV99782678; called by muse, mutect2, varscan2
- ZNF263 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.806); catalogued as rs755474014, COSV99526957; called by muse, mutect2, varscan2
- ZNF419 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692199; called by muse, mutect2, varscan2
- ZNF451 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 119/449 reads (27%) | catalogued as COSV100674929; called by muse, mutect2, varscan2
- ZNF516 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1383457551, COSV101487296; called by muse, mutect2, varscan2
- ZWINT | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100571517; called by muse, mutect2, varscan2
- ADAM33 | c.303del p.Q102Sfs*19 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, pindel
- BID | c.427dup p.M143Nfs*4 (on ENST00000317361 / NM_197966.2; = p.M97Nfs*4 on NM_001196.4) | Frame Shift Ins (INS) | VAF 17/72 reads (24%) | called by mutect2, pindel, varscan2
- CAPZB | c.699dup p.G234Wfs*14 (on ENST00000375142 / NM_001206540.3; = p.G234Wfs*28 on NM_004930.5) | Frame Shift Ins (INS) | VAF 36/135 reads (27%) | called by mutect2, pindel, varscan2
- CUL9 | c.1003dup p.R335Pfs*34 | Frame Shift Ins (INS) | VAF 34/262 reads (13%) | called by pindel, varscan2
- DCDC1 | c.2189C>A p.A730D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.448); called by muse, mutect2
- IGHV4-28 | c.289C>T p.Q97* | Nonsense Mutation (SNP) | VAF 127/468 reads (27%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.52_65del p.K18* | Frame Shift Del (DEL) | VAF 34/116 reads (29%) | called by mutect2, pindel
- AHNAK | c.7080A>G p.V2360= | Silent (SNP) | VAF 114/540 reads (21%) | catalogued as rs1394325009, COSV99947807; called by muse, mutect2, varscan2
- AHRR | c.609G>A p.Q203= | Silent (SNP) | VAF 61/130 reads (47%) | catalogued as COSV100327415; called by muse, mutect2, varscan2
- CFHR2 | c.630A>G p.S210= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as COSV100804336; called by muse, mutect2, varscan2
- FBL | c.696G>T p.V232= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV99695312; called by muse, mutect2, varscan2
- GBA3 | c.1017T>A p.S339= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV101545523; called by muse, mutect2, varscan2
- HYDIN | c.14544G>A p.A4848= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs373475539; called by muse, mutect2, varscan2
- IGKV1D-16 | c.288C>A p.T96= | Silent (SNP) | VAF 65/303 reads (21%) | catalogued as rs774477457; called by muse, mutect2, varscan2
- ITPKA | c.1338G>A p.L446= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99540928; called by muse, mutect2, varscan2
- KCNB1 | c.882C>T p.R294= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as rs757868422, COSV65566083; called by muse, mutect2, varscan2
- KCNB2 | c.75G>T p.V25= | Silent (SNP) | VAF 89/270 reads (33%) | catalogued as COSV101578808; called by muse, mutect2, varscan2
- LGALS7B | c.288C>T p.D96= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1202744937, COSV100153389; called by muse, mutect2, varscan2
- MATN4 | c.447G>A p.R149= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV100637049; called by muse, mutect2, varscan2
- MCHR2 | c.492G>T p.L164= | Silent (SNP) | VAF 76/188 reads (40%) | catalogued as COSV99912126; called by muse, mutect2, varscan2
- MOV10L1 | c.3027G>A p.L1009= | Silent (SNP) | VAF 64/247 reads (26%) | catalogued as COSV99433984; called by muse, mutect2, varscan2
- NOTCH4 | c.984C>T p.N328= | Silent (SNP) | VAF 45/203 reads (22%) | catalogued as rs770530863, COSV100900704; called by muse, mutect2, varscan2
- PAPPA2 | c.2880G>T p.P960= | Silent (SNP) | VAF 98/402 reads (24%) | catalogued as COSV100868256; called by muse, mutect2, varscan2
- PDZD9 | c.648G>T p.V216= (on ENST00000424898 / NM_001363519.1; = p.V156= on NM_173806.4) | Silent (SNP) | VAF 178/547 reads (33%) | catalogued as COSV99193334; called by muse, mutect2, varscan2
- PHC2 | c.1482G>A p.Q494= | Silent (SNP) | VAF 47/117 reads (40%) | catalogued as COSV99931133; called by muse, mutect2, varscan2
- PTPRR | c.417A>C p.G139= | Silent (SNP) | VAF 73/188 reads (39%) | catalogued as COSV99317714; called by muse, mutect2, varscan2
- RFX4 | c.1557C>G p.A519= (on ENST00000392842 / NM_213594.3; = p.A425= on NM_032491.6) | Silent (SNP) | VAF 76/209 reads (36%) | catalogued as COSV99985921; called by muse, mutect2, varscan2
- SPATA4 | c.573C>T p.N191= | Silent (SNP) | VAF 54/116 reads (47%) | catalogued as COSV99708987; called by muse, mutect2, varscan2
- ST14 | c.346C>T p.L116= | Silent (SNP) | VAF 57/120 reads (48%) | catalogued as COSV99598823; called by muse, mutect2, varscan2
- SULT1C3 | c.144T>C p.D48= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV100227497; called by muse, mutect2
- TIMP3 | c.237G>C p.V79= | Silent (SNP) | VAF 68/216 reads (31%) | catalogued as COSV99831177; called by muse, mutect2, varscan2
- TOP1 | c.309G>A p.K103= | Silent (SNP) | VAF 97/180 reads (54%) | catalogued as rs369651304; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2943C>T p.S981= | Silent (SNP) | VAF 72/169 reads (43%) | catalogued as COSV99511960; called by muse, mutect2
- VPS13B | c.8394G>T p.V2798= | Silent (SNP) | VAF 103/180 reads (57%) | catalogued as COSV100662202; called by muse, mutect2, varscan2
- CFAP47 | c.2844+37G>T | Intron (SNP) | VAF 43/76 reads (57%) | catalogued as COSV99935151; called by muse, mutect2, varscan2
